Somatic mutation profile of cancer-model specimen HCM-SANG-0295-C15-85A (3D Organoid; aliquot HCM-SANG-0295-C15-85A-01D-A78U-36), derived from the primary tumor of HCMI case HCM-SANG-0295-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0295-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38d098de-6868-4e3d-bff2-33957b1399f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0295-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0295-C15-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0860c121-0077-46db-81b5-cf4591ea4ab3

The open-access MAF lists 241 somatic variants for this specimen: 163 protein-altering or splice-affecting, 51 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 51, Intron 16, Nonsense Mutation 8, Frame Shift Del 5, 3'Flank 4, Splice Site 4, RNA 4, Splice Region 4, Frame Shift Ins 2, In Frame Del 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 396/799 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 225/226 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 141/277 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1258490638, COSV54093358; called by muse, mutect2, varscan2
- ADAMTS14 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 182/334 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs1029116007; called by muse, mutect2, varscan2
- AURKA | c.7del p.R3Dfs*25 | Frame Shift Del (DEL) | VAF 96/376 reads (26%) | catalogued as COSV53860935; called by mutect2, pindel, varscan2
- BRD7 | c.526A>T p.M176L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV67159761; called by muse, mutect2, varscan2
- BRINP2 | c.2018A>T p.K673M | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV64176463, COSV64177215; called by muse, mutect2, varscan2
- C10orf71 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs374875968; called by muse, mutect2, varscan2
- C1orf94 | c.485T>A p.L162H | Missense Mutation (SNP) | VAF 126/248 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV64913180; called by muse, mutect2, varscan2
- C20orf85 | c.255C>T p.V85= | Splice Region (SNP) | VAF 48/179 reads (27%) | catalogued as COSV64519360, COSV64519964; called by muse, mutect2, varscan2
- C9 | c.199A>T p.I67F | Missense Mutation (SNP) | VAF 202/404 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs138509694, COSV99662591; called by muse, mutect2, varscan2
- CALN1 | c.206G>A p.G69E (on ENST00000329008 / NM_001017440.3; = p.G111E on NM_031468.4) | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100210144; called by muse, mutect2, varscan2
- CFH | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV62778193; called by muse, mutect2, varscan2
- CLEC14A | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 111/251 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100643532; called by muse, mutect2, varscan2
- CLMN | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 145/283 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as rs778685020; called by muse, mutect2, varscan2
- COL6A6 | c.5617G>A p.G1873S | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs763694891; called by muse, mutect2, varscan2
- DCLK1 | c.1589A>C p.K530T | Missense Mutation (SNP) | VAF 181/383 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55189569, COSV55200088; called by muse, mutect2, varscan2
- DDX47 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as rs746101128; called by muse, mutect2, varscan2
- DNAH8 | c.10040G>A p.R3347Q | Missense Mutation (SNP) | VAF 158/283 reads (56%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.49); catalogued as rs772835642, COSV100543539; called by muse, mutect2, varscan2
- EDIL3 | c.1309T>C p.F437L | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as COSV99678002; called by muse, mutect2, varscan2
- ELOA2 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 452/945 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs749767940; called by muse, mutect2, varscan2
- EPB41L3 | c.2950A>G p.T984A | Missense Mutation (SNP) | VAF 128/245 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59467372; called by muse, mutect2, varscan2
- EPHB1 | c.2413A>G p.S805G | Missense Mutation (SNP) | VAF 262/535 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777732731; called by muse, mutect2, varscan2
- ERBB4 | c.1432T>G p.F478V | Missense Mutation (SNP) | VAF 98/195 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV53556787; called by muse, mutect2, varscan2
- FNTB | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 112/230 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769584940; called by muse, mutect2, varscan2
- GAB4 | c.685A>C p.R229= | Splice Region (SNP) | VAF 87/191 reads (46%) | catalogued as rs770727743; called by muse, mutect2, varscan2
- GABRA1 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 170/386 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV50105181; called by muse, mutect2, varscan2
- GLRX5 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 190/368 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.282); catalogued as rs1233466317; called by muse, mutect2, varscan2
- GPRC6A | c.1195A>G p.R399G | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV59952237; called by muse, mutect2, varscan2
- GRM6 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 206/425 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs182751201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IP6K3 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs367942403; called by muse, mutect2, varscan2
- ITGA1 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.362); catalogued as rs150093672, COSV50890398; called by muse, mutect2, varscan2
- ITGAE | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs763227795, COSV53994324; called by muse, mutect2, varscan2
- ITIH6 | c.2410G>T p.G804C | Missense Mutation (SNP) | VAF 160/162 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs1014707092; called by muse, mutect2, varscan2
- JAKMIP1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 134/284 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs1313972918, COSV51539800; called by muse, mutect2, varscan2
- KCNH3 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 255/520 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV99235624; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>G p.L966R | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- KLF8 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63847515; called by muse, mutect2, varscan2
- KMT2B | c.3003-2A>G p.X1001_splice | Splice Site (SNP) | VAF 45/87 reads (52%) | catalogued as COSV55856550, COSV99719393; called by muse, mutect2, varscan2
- LRRC38 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 201/384 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as rs919521539; called by muse, mutect2, varscan2
- LRRC3B | c.120T>G p.C40W | Missense Mutation (SNP) | VAF 117/252 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67519992; called by muse, mutect2, varscan2
- MACROD2 | c.1039C>A p.H347N (on ENST00000642719; = p.H319N on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV53986579; called by muse, mutect2, varscan2
- MED16 | c.2484-1G>A p.X828_splice | Splice Site (SNP) | VAF 264/596 reads (44%) | catalogued as rs1395288878, COSV54132478; called by muse, mutect2, varscan2
- MLH3 | c.3571G>T p.V1191F | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1420496802; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTSS2 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 145/312 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780793409; called by muse, mutect2, varscan2
- MYEOV | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 199/434 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs762892765; called by muse, mutect2, varscan2
- NID1 | c.3298C>T p.R1100W | Missense Mutation (SNP) | VAF 189/409 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746516796, COSV51625828; called by muse, mutect2, varscan2
- NKPD1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs976872693; called by muse, mutect2, varscan2
- NLGN4X | c.2318T>C p.L773P | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.216); catalogued as COSV52011412, COSV99322018; called by muse, mutect2, varscan2
- OBSCN | c.14824C>T p.R4942W | Missense Mutation (SNP) | VAF 177/366 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs763287256, COSV52753674; called by muse, mutect2, varscan2
- OR4C15 | c.735del p.H246Tfs*17 (on ENST00000314644; = p.H192Tfs*17 on NM_001001920.2) | Frame Shift Del (DEL) | VAF 97/247 reads (39%) | catalogued as COSV58951027; called by mutect2, pindel, varscan2
- OR8K1 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as rs1405594221, COSV54401343; called by muse, mutect2, varscan2
- PAPPA | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs756844986, COSV60280533; called by muse, mutect2, varscan2
- PARD6B | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 136/391 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775400612; called by muse, mutect2, varscan2
- PCDH9 | c.3215A>T p.E1072V (on ENST00000377865 / NM_203487.3; = p.E1038V on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/322 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100121698, COSV60526615; called by muse, mutect2, varscan2
- PCLO | c.10254A>T p.K3418N | Missense Mutation (SNP) | VAF 144/297 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV61657367; called by muse, mutect2, varscan2
- PLXNA4 | c.4666C>T p.R1556* | Nonsense Mutation (SNP) | VAF 124/233 reads (53%) | catalogued as rs752862207, COSV58104619; called by muse, mutect2, varscan2
- PRR16 | c.617G>A p.R206Q (on ENST00000407149 / NM_001300783.2; = p.R183Q on NM_016644.2) | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1162088448, COSV65397343, COSV65404957; called by muse, mutect2, varscan2
- PTP4A2 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs149882515; called by muse, mutect2, varscan2
- SEMA3E | c.337-1G>T p.X113_splice | Splice Site (SNP) | VAF 173/358 reads (48%) | catalogued as rs1311561381, COSV57081072; called by muse, mutect2, varscan2
- SH3D21 | c.1672G>A p.D558N (on ENST00000453908 / NM_001162530.2; = p.D447N on NM_024676.5) | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV99583929; called by muse, mutect2, varscan2
- SHANK2 | c.4736C>T p.P1579L | Missense Mutation (SNP) | VAF 298/604 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs781993277, COSV53593252, COSV53603178; called by muse, mutect2, varscan2
- SIGLEC12 | c.1569C>A p.D523E (on ENST00000291707 / NM_053003.4; = p.D405E on NM_033329.2) | Missense Mutation (SNP) | VAF 197/410 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV52458979, COSV99389688; called by muse, mutect2, varscan2
- SIPA1L2 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs1468613349; called by muse, mutect2, varscan2
- SLA | c.820T>G p.F274V (on ENST00000338087 / NM_001045556.3; = p.F314V on NM_006748.4) | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV55075605; called by muse, mutect2, varscan2
- SLC38A10 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV55843033; called by muse, mutect2, varscan2
- SLC8A3 | c.715T>C p.F239L | Missense Mutation (SNP) | VAF 142/288 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100776207; called by muse, mutect2, varscan2
- SLCO6A1 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 179/336 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0.139); catalogued as rs144293843, COSV65806739; called by muse, mutect2, varscan2
- SNED1 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 269/544 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs368117519; called by muse, mutect2, varscan2
- SPTBN4 | c.4748C>T p.S1583L | Missense Mutation (SNP) | VAF 135/280 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs1464093058, COSV58946110; called by muse, mutect2, varscan2
- SYNGAP1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 236/495 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53386630; called by muse, mutect2, varscan2
- TMEM68 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV58172104; called by muse, mutect2, varscan2
- TRHR | c.586T>A p.F196I | Missense Mutation (SNP) | VAF 284/437 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100305153, COSV61232746; called by muse, mutect2, varscan2
- VILL | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99379040; called by muse, mutect2, varscan2
- ZNF730 | c.1496A>C p.K499T | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV74168249, COSV74168289; called by muse, mutect2, varscan2
- ZSCAN1 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV56604480; called by muse, mutect2, varscan2
- ADAM10 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADGRB2 | c.3129G>A p.W1043* | Nonsense Mutation (SNP) | VAF 79/165 reads (48%) | called by muse, mutect2, varscan2
- ANKRD1 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 211/481 reads (44%) | called by muse, mutect2, varscan2
- ATM | c.4695T>A p.F1565L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ATP2B1 | c.2634A>C p.Q878H | Missense Mutation (SNP) | VAF 146/284 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP6V1H | c.751G>C p.A251P | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- C18orf63 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CADM1 | c.1219T>C p.F407L | Missense Mutation (SNP) | VAF 204/434 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAPRIN2 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 226/454 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- CCDC168 | c.1565A>G p.K522R | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CCNA1 | c.333A>C p.E111D | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- CCR5 | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 100/189 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP54 | c.7309T>G p.L2437V | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CFH | c.1822T>C p.S608P | Missense Mutation (SNP) | VAF 108/209 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CLEC4E | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 104/212 reads (49%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCC | c.1911A>C p.R637S | Missense Mutation (SNP) | VAF 192/429 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DDX1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- DHX36 | c.697_708del p.G233_K236del | In Frame Del (DEL) | VAF 17/107 reads (16%) | called by mutect2, pindel, varscan2
- DTX1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 138/257 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELANE | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 184/344 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FHOD3 | c.1456T>G p.L486V (on ENST00000359247 / NM_001281739.3; = p.L503V on NM_025135.5) | Missense Mutation (SNP) | VAF 172/380 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FMN2 | c.4597A>C p.S1533R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FOXE1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FTHL17 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCN1 | c.2448G>C p.K816N | Missense Mutation (SNP) | VAF 144/337 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- GDF5 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 141/467 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GRK2 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRK3 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY1B1 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- HCFC1 | c.6062C>T p.P2021L | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HECW1 | c.4055T>A p.L1352Q | Missense Mutation (SNP) | VAF 125/352 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIRA | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGDCC3 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- JCAD | c.3332C>T p.P1111L | Missense Mutation (SNP) | VAF 108/213 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KNG1 | c.229_234dup p.E77_I78dup | In Frame Ins (INS) | VAF 160/405 reads (40%) | called by mutect2, varscan2
- LAMA1 | c.309_310insC p.Y104Lfs*22 | Frame Shift Ins (INS) | VAF 153/414 reads (37%) | called by mutect2, pindel, varscan2
- LLGL2 | c.214_216del p.E72del | In Frame Del (DEL) | VAF 114/371 reads (31%) | called by mutect2, pindel, varscan2
- LRP2 | c.6509T>G p.L2170R | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- LRRK2 | c.1417A>C p.S473R | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MAGEC3 | c.1385A>G p.E462G | Missense Mutation (SNP) | VAF 123/123 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- MAGEL2 | c.83T>G p.V28G | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAP3K6 | c.330C>G p.F110L | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MMP9 | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 438/1319 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- MORC1 | c.1516_1517insG p.F506Cfs*3 | Frame Shift Ins (INS) | VAF 52/146 reads (36%) | called by mutect2, pindel, varscan2
- MSH4 | c.2245A>G p.N749D | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MXRA5 | c.5328C>A p.S1776R | Missense Mutation (SNP) | VAF 135/137 reads (99%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- NBEAL2 | c.3298T>G p.F1100V | Missense Mutation (SNP) | VAF 151/325 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NEGR1 | c.562T>G p.L188V | Missense Mutation (SNP) | VAF 78/148 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NEK11 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NFKBIZ | c.1134del p.S379Afs*30 | Frame Shift Del (DEL) | VAF 64/145 reads (44%) | called by pindel*, varscan2
- OR10G9 | c.397A>G p.S133G | Missense Mutation (SNP) | VAF 105/117 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- OTOGL | c.3079T>G p.F1027V (on ENST00000547103; = p.F1018V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCLO | c.3714A>C p.E1238D | Missense Mutation (SNP) | VAF 170/398 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCSK6 | c.2317C>T p.H773Y | Missense Mutation (SNP) | VAF 156/289 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POTEC | c.1270A>C p.S424R | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PTPRN | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- RAD23B | c.1007G>C p.G336A | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- REX1BD | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 160/297 reads (54%) | called by muse, mutect2, varscan2
- RYR2 | c.11562del p.Q3855Rfs*4 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by pindel, varscan2
- SDHC | c.418G>C p.G140R | Missense Mutation (SNP) | VAF 323/707 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEL1L2 | c.1821C>A p.D607E | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SELP | c.1615A>T p.I539F | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEM1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- SH3GL2 | c.977A>C p.N326T | Missense Mutation (SNP) | VAF 69/70 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC37A4 | c.851C>G p.S284* | Nonsense Mutation (SNP) | VAF 118/118 reads (100%) | called by muse, mutect2, varscan2
- SLC6A18 | c.973A>C p.R325= | Splice Region (SNP) | VAF 108/192 reads (56%) | called by muse, mutect2, varscan2
- SMCHD1 | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SPATA31E1 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 119/352 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SPIN2A | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 161/218 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SPOCK3 | c.366A>C p.K122N | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STRBP | c.1322T>G p.L441R | Missense Mutation (SNP) | VAF 251/361 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STS | c.1568A>C p.K523T | Missense Mutation (SNP) | VAF 181/182 reads (99%) | SIFT tolerated (0.5); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TBX22 | c.1487A>G p.D496G | Missense Mutation (SNP) | VAF 88/89 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TPTE | c.1566A>C p.K522N (on ENST00000618007 / NM_199261.4; = p.K504N on NM_199259.4) | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- TRAM1L1 | c.353A>C p.K118T | Missense Mutation (SNP) | VAF 103/175 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TSPAN10 | c.1096G>A p.G366S (on ENST00000574882 / NM_001290212.1; = p.G328S on NM_031945.4) | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.3964-2A>G p.X1322_splice (on ENST00000591111; = p.X1276_splice on NM_003319.4) | Splice Site (SNP) | VAF 136/262 reads (52%) | called by muse, mutect2, varscan2
- TXNL1 | c.840+4A>G | Splice Region (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- UGT3A1 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 111/214 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1950del p.F650Lfs*31 | Frame Shift Del (DEL) | VAF 76/181 reads (42%) | called by mutect2, pindel, varscan2
- UXT | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- WDFY4 | c.8278T>G p.F2760V | Missense Mutation (SNP) | VAF 169/333 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF429 | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 93/190 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF770 | c.907T>A p.F303I | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZRANB3 | c.221A>C p.Y74S | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZSCAN1 | c.1096G>T p.G366* | Nonsense Mutation (SNP) | VAF 66/165 reads (40%) | called by muse, mutect2, varscan2
- ABCB11 | c.3909G>C p.L1303= | Silent (SNP) | VAF 193/433 reads (45%) | catalogued as COSV55600000; called by muse, mutect2, varscan2
- ATRNL1 | c.2499A>C p.T833= | Silent (SNP) | VAF 109/235 reads (46%) | called by muse, mutect2, varscan2
- BEND4 | c.726T>G p.T242= | Silent (SNP) | VAF 120/241 reads (50%) | catalogued as rs1159508482, COSV72469196; called by muse, mutect2, varscan2
- CFAP61 | c.1449C>T p.T483= | Silent (SNP) | VAF 69/333 reads (21%) | called by muse, mutect2, varscan2
- CHST9 | c.184C>A p.R62= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs374613360, COSV99410495; called by muse, mutect2, varscan2
- CLUH | c.264C>T p.C88= (on ENST00000435359; = p.C126= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 142/142 reads (100%) | called by muse, mutect2
- CPXM1 | c.792G>A p.A264= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs750146849; called by muse, mutect2, varscan2
- CUBN | c.4611T>C p.S1537= | Silent (SNP) | VAF 126/241 reads (52%) | catalogued as COSV64708389; called by muse, mutect2, varscan2
- DOCK4 | c.2361C>G p.V787= | Silent (SNP) | VAF 131/275 reads (48%) | called by muse, mutect2, varscan2
- DSPP | c.1920A>G p.S640= | Silent (SNP) | VAF 165/349 reads (47%) | called by muse, mutect2, varscan2
- ESR1 | c.1702T>C p.L568= | Silent (SNP) | VAF 321/643 reads (50%) | called by muse, mutect2, varscan2
- FAM181B | c.411C>G p.V137= | Silent (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- FCRL5 | c.1452T>A p.T484= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as COSV100709462; called by muse, mutect2, varscan2
- GPR4 | c.39G>A p.S13= | Silent (SNP) | VAF 64/125 reads (51%) | catalogued as rs761612113, COSV59918715; called by muse, mutect2, varscan2
- GRM1 | c.588T>G p.T196= | Silent (SNP) | VAF 315/681 reads (46%) | catalogued as COSV51117494, COSV51140435; called by muse, mutect2, varscan2
- HIP1R | c.1458G>A p.A486= | Silent (SNP) | VAF 217/488 reads (44%) | catalogued as rs376969064; called by muse, mutect2, varscan2
- INSM2 | c.642G>T p.A214= | Silent (SNP) | VAF 83/171 reads (49%) | called by muse, mutect2, varscan2
- KIAA1109 | c.3451T>C p.L1151= | Silent (SNP) | VAF 128/246 reads (52%) | called by muse, mutect2, varscan2
- LGI1 | c.1122C>T p.H374= | Silent (SNP) | VAF 172/327 reads (53%) | catalogued as rs150515718, COSV65059098; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP2 | c.705T>A p.I235= | Silent (SNP) | VAF 186/408 reads (46%) | called by muse, mutect2, varscan2
- MAST4 | c.3342C>T p.S1114= (on ENST00000403625 / NM_001164664.2; = p.S925= on NM_015183.3) | Silent (SNP) | VAF 167/303 reads (55%) | called by muse, mutect2, varscan2
- MBD5 | c.3993A>G p.K1331= | Silent (SNP) | VAF 233/470 reads (50%) | called by muse, mutect2, varscan2
- MED13 | c.3477A>G p.A1159= | Silent (SNP) | VAF 140/450 reads (31%) | catalogued as rs1423021656; called by muse, mutect2, varscan2
- MED13 | c.2379A>G p.E793= | Silent (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2
- NBN | c.1992T>C p.I664= | Silent (SNP) | VAF 165/238 reads (69%) | catalogued as COSV55371130; called by muse, mutect2, varscan2
- OR51G2 | c.609C>T p.Y203= | Silent (SNP) | VAF 131/257 reads (51%) | catalogued as rs754454942, COSV58993216; called by muse, mutect2, varscan2
- OR5T2 | c.681T>A p.S227= | Silent (SNP) | VAF 62/115 reads (54%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- OR6C3 | c.555T>A p.S185= | Silent (SNP) | VAF 105/201 reads (52%) | catalogued as COSV101110306; called by muse, mutect2, varscan2
- OR6K3 | c.975G>A p.V325= (on ENST00000368146; = p.V309= on NM_001005327.2) | Silent (SNP) | VAF 52/91 reads (57%) | catalogued as rs752468682; called by muse, mutect2
- PAGE5 | c.96A>G p.E32= | Silent (SNP) | VAF 71/71 reads (100%) | called by muse, mutect2, varscan2
- PCLO | c.627T>G p.P209= | Silent (SNP) | VAF 114/260 reads (44%) | called by muse, mutect2, varscan2
- PCSK6 | c.204C>G p.P68= | Silent (SNP) | VAF 77/153 reads (50%) | catalogued as rs1462684341; called by muse, mutect2, varscan2
- POLRMT | c.1443G>C p.R481= | Silent (SNP) | VAF 170/319 reads (53%) | catalogued as rs373669217; called by muse, mutect2, varscan2
- PPFIA4 | c.2649C>G p.L883= (on ENST00000447715; = p.L884= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 207/451 reads (46%) | called by muse, mutect2, varscan2
- RAD21 | c.933A>C p.I311= | Silent (SNP) | VAF 97/150 reads (65%) | called by muse, mutect2, varscan2
- RASSF9 | c.127C>T p.L43= | Silent (SNP) | VAF 61/129 reads (47%) | called by muse, mutect2, varscan2
- RBAK | c.1764A>G p.V588= | Silent (SNP) | VAF 55/97 reads (57%) | catalogued as COSV100806593; called by muse, mutect2, varscan2
- RHPN2 | c.543C>T p.V181= | Silent (SNP) | VAF 311/652 reads (48%) | catalogued as rs749127623; called by muse, mutect2, varscan2
- RTN2 | c.597G>A p.S199= | Silent (SNP) | VAF 112/231 reads (48%) | catalogued as rs764702354, COSV55595836; called by muse, mutect2, varscan2
- SLC12A1 | c.2277T>G p.G759= | Silent (SNP) | VAF 57/114 reads (50%) | called by muse, mutect2, varscan2
- SLC35D3 | c.798C>A p.T266= | Silent (SNP) | VAF 209/397 reads (53%) | catalogued as rs765312973; called by muse, mutect2, varscan2
- SNCA | c.66C>A p.T22= | Silent (SNP) | VAF 193/395 reads (49%) | catalogued as rs754909792, COSV61136099; called by muse, mutect2, varscan2
- SORCS3 | c.2779A>C p.R927= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV63794378, COSV63795291; called by muse, mutect2, varscan2
- SSTR4 | c.123C>T p.D41= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV54798175; called by muse, mutect2, varscan2
- TAS2R4 | c.591C>G p.S197= | Silent (SNP) | VAF 80/180 reads (44%) | catalogued as COSV56094294; called by muse, mutect2, varscan2
- TBX20 | c.1056T>G p.S352= | Silent (SNP) | VAF 183/439 reads (42%) | called by muse, mutect2, varscan2
- TP53BP1 | c.4617G>A p.P1539= | Silent (SNP) | VAF 112/206 reads (54%) | catalogued as rs1354868872, COSV55499102; called by muse, mutect2, varscan2
- TPO | c.435T>G p.T145= | Silent (SNP) | VAF 211/463 reads (46%) | catalogued as COSV61096136; called by muse, mutect2, varscan2
- USP17L7 | c.105T>G p.T35= | Silent (SNP) | VAF 368/1220 reads (30%) | called by muse, mutect2, varscan2
- VXN | c.243G>A p.P81= | Silent (SNP) | VAF 53/141 reads (38%) | catalogued as rs753064397; called by muse, mutect2
- ZNF572 | c.216A>G p.P72= | Silent (SNP) | VAF 96/302 reads (32%) | called by muse, mutect2, varscan2
- AC010507.1 | chr19:200767 C>T | 3'Flank (SNP) | VAF 11/484 reads (2%) | catalogued as rs752589210; called by muse, mutect2
- AC136628.2 | n.862A>T | RNA (SNP) | VAF 223/529 reads (42%) | called by muse, mutect2, varscan2
- ATAD3B | c.645+22C>T | Intron (SNP) | VAF 186/360 reads (52%) | catalogued as rs1167505667; called by muse, mutect2, varscan2
- CCDC169 | chr13:36227336 C>G | 3'Flank (SNP) | VAF 82/156 reads (53%) | called by muse, mutect2, varscan2
- CDK15 | c.1059-3500A>C | Intron (SNP) | VAF 88/172 reads (51%) | catalogued as rs1230495617; called by muse, mutect2, varscan2
- CFAP74 | c.2176+202C>T | Intron (SNP) | VAF 48/734 reads (7%) | catalogued as rs749766387; called by muse, mutect2
- CSF3R | c.1723+23del | Intron (DEL) | VAF 100/304 reads (33%) | catalogued as rs1256632266; called by mutect2, pindel, varscan2
- GALNT17 | c.239-35057A>C | Intron (SNP) | VAF 46/97 reads (47%) | catalogued as COSV100352519; called by muse, mutect2
- INTS4 | c.2228+17G>A | Intron (SNP) | VAF 95/261 reads (36%) | catalogued as rs770389967; called by muse, mutect2, varscan2
- IQCN | c.2616+239G>A | Intron (SNP) | VAF 221/457 reads (48%) | catalogued as COSV66575624; called by muse, mutect2, varscan2
- JAM2 | c.822-957T>G | Intron (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- KCNMA1 | c.*2247A>C | 3'UTR (SNP) | VAF 73/150 reads (49%) | called by muse, mutect2, varscan2
- MC3R | c.-98A>C | 5'UTR (SNP) | VAF 276/409 reads (67%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40545984 A>C | 3'Flank (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- MUC20P1 | n.986A>T | RNA (SNP) | VAF 240/1148 reads (21%) | called by muse, varscan2
- PPFIA2 | c.1267-113A>C | Intron (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- PRKRA | c.65+47G>A | Intron (SNP) | VAF 107/207 reads (52%) | catalogued as rs1353383540; called by muse, mutect2, varscan2
- RIMS2 | c.2084-854T>A | Intron (SNP) | VAF 44/133 reads (33%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.2338C>T | RNA (SNP) | VAF 72/137 reads (53%) | called by muse, mutect2, varscan2
- SLAMF8 | chr1:159841186 C>T | 3'Flank (SNP) | VAF 122/287 reads (43%) | called by muse, mutect2, varscan2
- SLC19A2 | c.1031-17T>G | Intron (SNP) | VAF 63/119 reads (53%) | catalogued as rs749521584; called by muse, mutect2, varscan2
- SMAD2 | c.655+15T>G | Intron (SNP) | VAF 103/202 reads (51%) | called by muse, mutect2, varscan2
- SMARCD2 | c.216+60G>A | Intron (SNP) | VAF 46/129 reads (36%) | called by muse, mutect2, varscan2
- SNORD116-27 | n.87A>G | RNA (SNP) | VAF 92/180 reads (51%) | called by muse, mutect2, varscan2
- SPTA1 | c.6789-13T>C | Intron (SNP) | VAF 78/141 reads (55%) | called by muse, mutect2, varscan2
- TMEFF2 | c.1029-49T>G | Intron (SNP) | VAF 119/274 reads (43%) | catalogued as rs552083512, COSV55836558, COSV99772019; called by muse, mutect2, varscan2
- TRPC6 | c.*24A>G | 3'UTR (SNP) | VAF 67/114 reads (59%) | catalogued as rs369102556; called by muse, mutect2, varscan2
